Somatic mutation profile of tumor specimen HCM-BROD-0711-C64-01A (aliquot HCM-BROD-0711-C64-01A-01D-A881-36) from HCMI case HCM-BROD-0711-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 63.8 years (23,306 days).
Specimen HCM-BROD-0711-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 661d5bcd-3d79-49bd-aa7d-9c6c3a6d2e00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0711-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0711-C64-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/881f4757-4adb-4270-a779-b7f97e2192cb

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 4, Silent 3, 5'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY7 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 327/708 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs150835400; called by muse, mutect2, varscan2
- AQP4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 34/975 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as COSV67219488; called by muse, mutect2
- LRRC72 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 225/518 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.072); catalogued as rs886746919; called by muse, mutect2, varscan2
- PXDNL | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 43/883 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs1218405990, COSV62482671; called by muse, mutect2
- RIMS1 | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.92); catalogued as COSV53439494; called by muse, mutect2
- SLC4A7 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 57/299 reads (19%) | catalogued as COSV99840147; called by muse, mutect2, varscan2
- TRHDE | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 102/434 reads (24%) | catalogued as rs762647325, COSV53832847; called by muse, mutect2, varscan2
- UGT2B15 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 18/461 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV57735114; called by muse, mutect2
- ZNF521 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 164/510 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as rs140546909; called by muse, mutect2, varscan2
- CDKN1A | c.248_262delinsC p.R83Pfs*41 | Frame Shift Del (DEL) | VAF 187/219 reads (85%) | called by pindel, varscan2*
- CHD4 | c.3678_3689del p.K1226_D1230delinsN (on ENST00000357008 / NM_001363606.2; = p.K1239_D1243delinsN on NM_001273.5) | In Frame Del (DEL) | VAF 104/308 reads (34%) | called by mutect2, pindel, varscan2
- EDN3 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 165/383 reads (43%) | called by muse, mutect2, varscan2
- GRHL2 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 156/334 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LTN1 | c.2554C>G p.Q852E | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- MAPK4 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 28/700 reads (4%) | called by muse, mutect2
- SLC45A3 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- VSIR | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 242/542 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WRN | c.494C>G p.A165G | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCAF16 | c.447C>T p.T149= | Silent (SNP) | VAF 274/582 reads (47%) | called by muse, mutect2, varscan2
- HEMK1 | c.30C>T p.A10= | Silent (SNP) | VAF 30/466 reads (6%) | called by muse, mutect2
- ZNF724 | c.1767C>A p.P589= | Silent (SNP) | VAF 103/241 reads (43%) | called by muse, mutect2, varscan2
- FBLIM1 | c.-1C>T | 5'UTR (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
